Gene-level copy-number profile of tumor specimen TCGA-BR-8081-01A from TCGA case TCGA-BR-8081, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.4 years (26,095 days).
Specimen TCGA-BR-8081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.c2e36e6a-3bcd-4482-bc36-dd8d147d0a8a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8081-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f6e4e728-f2ad-4dde-8f38-b062b6666a93

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 197; copy number 2: 59,129; copy number 3: 487.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8081-01A-11D-2338-01): tumor purity 0.37, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,127,400–14,636,524, 7 genes (within-gene range 0–1): AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 197. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
